Surgical pathology report (de-identified scan), TCGA case TCGA-IN-A6RN, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-IN-A6RN-01A (Primary Tumor).

[page 1 of 2]
FINAL DIAGNOSIS:

Collection Date:

PART 1: LIVER, LEFT LATERAL SEGMENT, BIOPSY -

- A. SUBCAPSULAR LIVER BIOPSY WITH FOCAL FIBROSIS AND BILE DUCTULAR PROLIFERATION.
- B. THERE IS NO EVIDENCE OF MALIGNANCY.

PART 2: LYMPH NODE, LEFT GASTRIC TISSUE, RESECTION -

- METASTATIC ADENOCARCINOMA TO ONE OF TWO LYMPH NODES (1/2) CONFIRMED USING IMMUNOHISTOCHEMICAL STAIN TO AE1/3.

PART 3: LYMPH NODE, LEVEL 7, RESECTION -

- THERE IS NO EVIDENCE OF MALIGNANCY IN ONE ANTHRACOTIC LYMPH NODE (0/1).

PART 4: LYMPH NODE, PARAESOPHAGEAL NEAR PERICARDIUM, RESECTION -

- A. NERVE AND FIBROADIPOSE TISSUE.
- B. THERE IS NO EVIDENCE OF MALIGNANCY.

PART 5: ESOPHAGUS AND STOMACH, ESOPHAGOGASTRECTOMY -

- A. ADENOCARCINOMA, MODERATELY DIFFERENTIATED (2.0 CM) CENTERED IN PROXIMAL GASTRIC MUCOSA, INVOLVING GE JUNCTION SQUAMOUS MUCOSA AND EXTENDING INTO BUT NOT THROUGH SUBMUCOSA.
- B. LYMPHOVASCULAR INVASION PRESENT.
- C. PERINEURAL INVASION NOT IDENTIFIED.
- D. METASTATIC ADENOCARCINOMA INVOLVING FOUR OF FIFTEEN LYMPH NODES (4/15).
- E. SURGICAL MARGINS (PROXIMAL, DISTAL AND ADVENTITIAL) NEGATIVE FOR MALIGNANCY.
- F. PATHOLOGIC STAGE = pT1b N2 (see synoptic note).
- G. NON-TUMOROUS GE JUNCTION MUCOSA WITH BARRETT'S ESOPHAGUS.
- H. NEGATIVE HER2 (1+) STAINING, SEE COMMENT.

ICD-O-3

PART 6: LYMPH NODE, PERIGASTRIC, RESECTION -

- METASTATIC ADENOCARCINOMA TO ONE LYMPH NODE (1/1).

PART 7: LYMPH NODE, UPPER PARAESOPHAGEAL, RESECTION -

- A. THERE IS NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1).
- B. MÖNKEBERG'S ARTERIOSCLEROSIS.

PART 8: LYMPH NODE, MID PARAESOPHAGEAL, RESECTION -

- THERE IS NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1).

PART 9: LYMPH NODE, PROXIMAL PARAESOPHAGEAL, RESECTION -

- THERE IS NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1).

PART 10: LYMPH NODE, SUBCARINAL, LEVEL VII, RESECTION -

- THERE IS NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1).

PART 11: LYMPH NODE, GASTRIC FAT, RESECTION -

- METASTATIC ADENOCARCINOMA TO ONE OUT OF TWO LYMPH NODES (1/2) WITH EXTRANODAL LYMPHOVASCULAR INVASION PRESENT.

PART 12: LYMPH NODE, GASTROESOPHAGEAL FAT, RESECTION -

- METASTATIC ADENOCARCINOMA TO TWO OUT OF FIVE LYMPH NODES (2/5) WITH EXTRANODAL LYMPHOVASCULAR INVASION IDENTIFIED.

PART 13: ESOPHAGUS AND STOMACH, EEA RINGS, RESECTION -

- A. SEGMENT OF ESOPHAGEAL WALL WITH UNREMARKABLE SQUAMOUS MUCOSA.
- B. SEGMENT OF GASTRIC WALL WITH REACTIVE OXYNTIC MUCOSA.
- C. THERE IS NO EVIDENCE OF MALIGNANCY.

PART 14: STOMACH, FINAL GASTRIC MARGIN, RESECTION -

- A. GASTRIC WALL WITH REACTIVE OXYNTIC MUCOSA.
- B. THERE IS NO EVIDENCE OF MALIGNANCY.

COMMENT:

Part 5. Esophagus and stomach, esophagogastrrectomy -

This morphology of the tumor is similar to previous adenocarcinoma seen in Part one of the gastrocardiac retroflex biopsy [redacted] from [redacted] slides 5G and 5E and immunohistochemical stain to HER2 were reviewed at [redacted]

at [redacted] on [redacted] All agreed that HER2 is negative with 1+ staining, defined by some membranous reactivity in >10% of cells.

Adenocarcinoma NOS
8/40/13
CSCF
Site: Hart's esophageal
junction C16.0
path
Cardia C16.0
QW 7/23/13

[page 2 of 2]
CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY ESOPHAGEAL TUMORS****----- MACROSCOPIC -----**

SPECIMEN TYPE: Esophagogastrectomy
TUMOR SITE: Tumor midpoint in proximal stomach or cardia (within 5cm of EGJ) AND tumor involves esophagogastric junction
TUMOR SIZE: Greatest dimension: 2.0 cm
Additional dimensions: 1.5 X 0.3 cm

----- MICROSCOPIC -----

HISTOLOGIC TYPE: Adenocarcinoma
HISTOLOGIC GRADE: G2
PATHOLOGIC STAGING (pTNM)
pT1b
pN2
Number of lymph nodes examined: 15
Number of lymph nodes involved: 5
pM Not applicable
No prior treatment

PRIOR TREATMENT:
MARGINS

Proximal margin uninvolved by invasive carcinoma
Distal margin uninvolved by invasive carcinoma
Circumferential (adventitial) margin uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: 0.5 mm
Specify margin: adeventitial margin

ANGIOLYMPHATIC INVASION:

Present

ADDITIONAL PATHOLOGIC FINDINGS:

Intestinal metaplasia (Barrett's esophagus)

Source: NCI Genomic Data Commons file cbaf1de6-0cef-406a-8a89-e96fa7f19af7 (TCGA-IN-A6RN.B82ABADE-D379-4BE5-841C-C196F1965046.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).